Surgical pathology report (de-identified scan), TCGA case TCGA-LK-A4O7, project TCGA-MESO (Mesothelioma), tissue source site University of Pittsburgh, specimen TCGA-LK-A4O7-01A (Primary Tumor).

FINAL DIAGNOSIS:

- PART 1: 6TH RIB, RESECTION -**
A. BONE MARROW WITH TRILINEAGE HEMATOPOIESIS, NEGATIVE FOR METASTATIC TUMOR.
B. ATTACHED SKELETAL MUSCLE AND ADIPOSE TISSUE FREE OF TUMOR.
- PART 2: PLEURAL TISSUE, PLEURECTOMY -**
MALIGNANT MESOTHELIOMA, EPITHELIOID TYPE (SEE COMMENT).
- PART 3: SUBCARINAL LYMPH NODE, BIOPSY -**
FRAGMENTED LYMPH NODE (THREE (3) FRAGMENTS) NEGATIVE FOR METASTATIC MESOTHELIOMA WITH ANTHRACOSIS.
- PART 4: LEVEL 5 LYMPH NODE, BIOPSY -**
ONE OF THREE (1/3) FRAGMENTS OF LYMPH NODE POSITIVE FOR METASTATIC MESOTHELIOMA WITH ANTHRACOSIS.
- PART 5: LEVEL 11 LYMPH NODE, BIOPSY -**
FOUR OF FOUR (4/4) FRAGMENTS OF LYMPH NODE POSITIVE FOR METASTATIC MESOTHELIOMA WITH ANTHRACOSIS.
- PART 6: LEVEL 7 ZETA LYMPH NODE, BIOPSY -**
THREE OF THREE (3) LYMPH NODES POSITIVE FOR METASTATIC MESOTHELIOMA WITH ANTHRACOSIS.
- PART 7: LEVEL 9 LYMPH NODE, BIOPSY -**
A. THREE OF THREE (3) FRAGMENTS OF LYMPH NODE POSITIVE FOR METASTATIC MESOTHELIOMA WITH EXTRANODAL EXTENSION.
B. TUMOR PRESENT IN THE SOFT TISSUE.
- PART 8: LOWER LOBE LEVEL 10 LYMPH NODE, BIOPSY -**
ONE OF ONE (1/1) LYMPH NODE POSITIVE FOR METASTATIC MESOTHELIOMA WITH ANTHRACOSIS.
- PART 9: LEFT LUNG WITH PORTION OF PERICARDIUM, MEDIASTINAL FAT AND DIAPHRAGM, LEFT PLEURAL PNEUMONECTOMY -**
A. DIFFUSE MALIGNANT EPITHELIOID MESOTHELIOMA EXTENSIVELY INVOLVING THE ENTIRE PLEURA
B. TUMOR INFILTRATING PERICARDIUM BUT NOT THROUGH IT.
C. TUMOR INFILTRATING DIAPHRAGMATIC MUSCLE BUT NOT THROUGH IT.
D. TUMOR INFILTRATING ADJACENT MEDIASTINAL ADIPOSE TISSUE.
E. TUMOR FOCALLY INFILTRATING ADJACENT LUNG PARENCHYMA.
F. LYMPHOVASCULAR INVASION PRESENT.
G. BRONCHIAL AND VASCULAR MARGINS OF RESECTION FREE OF TUMOR.
H. THREE OF THREE (3/3) PERIBRONCHIAL LYMPH NODES POSITIVE FOR METASTATIC MESOTHELIOMA.
I. LUNG PARENCHYMA WITH ATELECTASIS AND EMPHYSEMATOUS CHANGES.
J. 7TH EDITION AJCC PATHOLOGIC TNM STAGE: pT3 N2 MX.

COMMENT:

The immunostains are as follows:
Calretinin - positive
WT1 - positive
D240 - positive
Cytokeratin AE1/3 - positive
P72.3 - negative
All controls stained adequately.

ICD-0-3
Mesothelioma, epithelioid, NOS 9052/3
Site: pleura, NOS. C38.4
w 9/25/12

The morphology and immunostain pattern support the diagnosis.

The resection edges of pericardium, diaphragm and mediastinum appear free of tumor. Due to the nature of the disease please correlate clinically for the completeness of resection.

CASE SYNOPSIS:

SYNOPTIC DATA - PRIMARY MESOTHELIOMA

SPECIMEN:	ICD-0-3	Other: pleura, lung, pericardium, diaphragm and mediastinal fat
PROCEDURE:	ICD-9-CM	Other: pleural pneumonectomy
SPECIMEN INTEGRITY:	ICD-9-CM	Intact
SPECIMEN LATERALITY:	ICD-9-CM	Left
TUMOR SITE:	ICD-9-CM	Visceral pleura
TUMOR FOCALITY:	ICD-9-CM	Diffuse
HISTOLOGIC TYPE:	ICD-9-CM	Epithelioid mesothelioma
TUMOR EXTENSION:	ICD-9-CM	Confluent visceral pleural tumor (including fissure)
	ICD-9-CM	Into but not through diaphragm
	ICD-9-CM	Lung parenchyma
	ICD-9-CM	Into mediastinal fat
	ICD-9-CM	Into but not through pericardium
MARGINS:	ICD-9-CM	Cannot be assessed
TREATMENT EFFECT:	ICD-9-CM	Not applicable

MARGINS:
TREATMENT EFFECT:
PATHOLOGIC STAGING (pTNM)

pT3
pN2
Number cannot be determined
pM Not applicable
Immunohistochemical stain(s)

ICD-9-CM Discrepancy		☒
Qual/Synch/Unos Primary Notes		☒

Source: NCI Genomic Data Commons file af34a316-b8b8-468c-b40d-c839292c1d9f (TCGA-LK-A4O7.A9C93568-D495-49A1-BF59-B14B9B1D90CC.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).